Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4354, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4354-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

History of metastatic RCC.

Specimens Submitted:

1: Kidney and colon, left nephrectomy and partial colectomy

2: SP: Colon, left, segmental resection

3: Lymph nodes, para-aortic, excision

4: Adrenal and lymph nodes, left and suprahilar, excision

5: Lymph nodes, interaortocaval, excision

DIAGNOSIS:

1. Kidney and colon, left nephrectomy and partial colectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with focal sarcomatoid features. Tumor shows large areas of necrosis and fibrosis (grossly, 50-60% of the tumor
is viable)

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 16.5 cm.

Local Invasion (for renal cortical types):

Involves Gerota's fascia

Extends into renal pelvis

Involves renal sinus fat

and invades into adherent colonic wall.

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion is identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal interstitial chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT4 Tumor invades beyond Gerota's fascia

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Comment: Immunostains for CD10 and Carbonic Anhydrase IX support the above interpretation.

2. SP: Colon, left, segmental resection
Benign segment of colon.
Omentum, negative for tumor.
Four lymph nodes, negative for tumor (0/4)

3. Lymph nodes, para-aortic, excision:

Lymph Nodes:

Number of nodes examined:17
Number of metastatic nodes:1
The largest metastatic node is 6cm
Perinodal (extracapsular) extension identified
The metastatic renal cell carcinoma measures approximately 3 mm in maximum diameter.

Comment: Immunostains for AE1/AE3, CD10 and Carbonic Anhydrase IX support the above interpretation.

4. Adrenal and lymph nodes, left and suprahilar, excision:

Lymph Nodes:

Not involved
Number of nodes examined:3
Benign adrenal gland

5. Lymph nodes, Interaortocaval, excision:

Lymph Nodes:

Not involved
Number of nodes examined:2

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CA-1X.	
	CD10	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	
	CD10	
	CA-1X.	
	NEG CONT	
	IMM RECUT	

Gross Description:

1).The specimen is received fresh labeled "left kidney and left colon" and consists of a kidney with attached ureter, renal vessels, perinephric fat and segment of colon weighing 1373 g in total. The kidney measures 21 x 11.5 x 9 cm. The attached ureter measures 16 cm in length and 0.2 cm in diameter. The attached renal vein measures 0.5 cm in length and 2.0 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. A segment of colon measuring 11 cm in length by 4 cm in

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

diameter, is adhered to the kidney. The serosal surface is pink-tan and smooth. No adrenal gland is grossly identified. The kidney is inked black and bivalved to reveal a solid mass with a heterogeneous cut surface measuring 16.5 x 13 x 8 cm, replacing the entire upper pole of the kidney. The mass is lobulated, with a dark red to bright yellow to tan and focally gelatinous cut surface. Large areas of hemorrhage and necrosis are identified. However, 50- 60% of the tumor appears grossly viable. The mass extends through the capsule to grossly involve the colonic serosa and wall. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.6 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted for [redacted] and for permanent sections.

Summary of sections:

UVM -- ureteral and vessel margins
T-- tumor
TE -- tumor extending through capsule
TC - tumor with involvement of colon wall
THF-- tumor with hilar fat
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney
CM -- colon margins

2). The specimen is received fresh labeled, "segment left colon", and consists of segment of large bowel measuring 12.9 cm long with an open circumference averaging 7.2 cm. The serosal surface is tan pink and grossly unremarkable. The specimen is opened to reveal colonic wall thickness of 0.3 cm and congested mucosa. No ulceration or any masses grossly identified. Multiple lymph nodes identified ranging from 0.3 to 0.5 cm in greatest dimension. Attached portion of omentum measures 12.0 x 8.0 x 0.5 cm and is grossly unremarkable. Representative sections submitted.

Summary of sections:

OM - one end margin
OPM - opposite end margin
RS - representative sections
LN - lymph nodes
O - omentum

3). The specimen is received in formalin, labeled "Para-aortic lymph nodes " and consists of multiple pink tan firm lymph nodes ranging from 1 to 6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph node
QLN-quadrisectioned largest lymph node

4). The specimen is received in formalin, labeled "Left adrenal suprarenal lymph nodes) it consist of an unoriented portion of fibroadipose tissue measuring 7 x 3 x 3 cm. The specimen weighs 33.5grams after fixation. The specimen is inked in black and serially sectioned to reveal a golden orange ill defined adrenal gland with attached adipose tissue measuring 5x 2.6 x 0.7cm. Cut sections reveal a centrally located cavity containing a yellow soft material. Five possible lymph node are identified measuring 1cm in average dimension. Representative sections are submitted. The specimen has been photographed.

Summary of sections:

A -- adrenal
PLN-possible lymph nodes

5). The specimen is received in formalin, labeled "Interaortocaval lymph nodes" and consists of two pink tan firm lymph nodes measuring 1 and 1.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph node

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

BLN-- bisected lymph node

Summary of Sections:

Part 1: Kidney and colon, left nephrectomy and partial colectomy

Block	Sect. Site	PCs
2	cm	2
1	k	1
1	rp	1
7	t	7
1	tc	1
1	te	1
2	thf	2
1	tk	1
4	tsf	4
1	uvm	1

Part 2: SP: Colon, left, segmental resection

Block	Sect. Site	PCs
1	LN	1
1	O	1
1	OM	1
1	OPM	1
2	RS	2

Part 3: Lymph nodes, para-aortic, excision

Block	Sect. Site	PCs
2	BLN	2
4	LN	13
2	QLN	4

Part 4: Adrenal and lymph nodes, left and supra hilar, excision

Block	Sect. Site	PCs
4	A	7
2	PLN	4

Part 5: Lymph nodes, interaortocaval, excision

Block	Sect. Site	PCs
1	BLN	2
1	LN	1

Source: NCI Genomic Data Commons file 4a6a98b4-c58a-483a-b122-52bf4e490c06 (TCGA-BP-4354.02269FEB-D63F-4330-B137-1206532AF4D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).